Surgical pathology report (de-identified scan), TCGA case TCGA-85-8584, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-85-8584-01A (Primary Tumor).

[page 1 of 4]
[REDACTED]

Case ID	Gross Description
[REDACTED]	Lobe with the lobar bronchus obstructed by a parahilar tumoral structure of 4/4/3.5 cm in diameter; the tumor is well-limited, with accentuated anthracotic tattoo.

[page 2 of 4]
Microscopic Description	Diagnosis Details
TUMOR FRAGMENT: Bronchopulmonary neoplasm of the spinocellular epidermoid carcinoma type without keratinization, G2, formed of a monomorphous cellularity with nuclear atypias and hotbeds of necrosis, with papillary pattern; fibrous-inflammatory stromal reaction. INTERLOBAR LYMPH NODE: No metastases. LYMPH NODE STATION X: Lymph node with neoplastic infiltrates of epidermoid carcinoma and small hotbeds of necrosis	

[page 3 of 4]
Comments	Formatted Path Report
	LUNG TISSUE CHECKLIST Specimen type: Lobectomy Tumor site: Lung Tumor size: 4 x 4 x 3.5 cm Histologic type: Squamous cell carcinoma Histologic grade: Moderately differentiated Tumor extent: Not specified Other tumor nodules: Not specified Lymph nodes: 1/2 positive for metastasis (Regional 1/2) Lymphatic invasion: Present Venous invasion: Not specified Margins: Not specified Evidence of neo-adjuvant treatment: Not specified Additional pathologic findings: Not specified Comments: Right- upper

[page 4 of 4]
[REDACTED]	ID	Excision date
[REDACTED]		[REDACTED]

Source: NCI Genomic Data Commons file 798021ff-e9b9-4902-aae6-39a0f22dc89c (TCGA-85-8584.C7614470-D0E1-4F08-87F7-E16706C5B830.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).